TCGA case TCGA-2G-AAGT — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/320995df-9ef7-460c-aa37-e232e2d4e327

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 30 years; Year of birth: 1972; Vital status: Alive.

Diagnoses (2)
1. Mixed germ cell tumor (the primary disease): ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 30.0 years (10,967 days); Year of diagnosis: 2002; Method of diagnosis: Orchiectomy; AJCC staging edition: 5th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,406 days (12.1 years); Ajcc serum tumor markers: S2.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Post Adjuvant Therapy.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 11 days; Days to treatment end: 71 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Mixed germ cell tumor), site: Intra-abdominal lymph nodes. Age at diagnosis: 30.1 years (10,982 days); Days to diagnosis: 15 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 15 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 15 days.
- Days to follow up: 3,789 days (10.4 years); Disease response: Tumor Free.
- Days to follow up: 4,406 days (12.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4: Lactate Dehydrogenase 374; Alpha Fetoprotein 450; Human Chorionic Gonadotropin 58.1.
- Day 9: Lactate Dehydrogenase 400; Alpha Fetoprotein 322; Human Chorionic Gonadotropin 38.1.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Esophageal Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAGT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 200 mg.
  Slide TCGA-2G-AAGT-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAGT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAGT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Non-Seminoma, Yolk Sac Tumor.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Teratoma (Mature); Histologic diagnosis percent: 20.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 374; Pre orchi hcg: 58.1; Pre orchi afp: 450.4.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 400; Post orchi hcg: 38.1; Post orchi afp: 322.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: Yes - After chemotherapy; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: Yes - After chemotherapy; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,406 days; disease-specific survival: no event (censored), 4,406 days; disease-free interval: event (new tumor event after initially disease-free), 15 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 15 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAGT-01A-11D-A42X-01): tumor purity 0.81, ploidy 2.4, whole-genome doublings 1.
